MMRF case MMRF_1665 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3c77321e-e681-4211-9e0c-816fecfe0544

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.6 years (23,597 days); ISS stage: I; Days to last known disease status: 1,219 days (3.3 years); Days to last follow up: 1,219 days (3.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 309 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 121 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 309 days; Days to treatment end: 309 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Lenalidomide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 432 days (1.2 years); Days to treatment end: 831 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 436 days (1.2 years); Days to treatment end: 932 days (2.6 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 936 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 3.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.507 mg/dL; Immunoglobulin G 44.6 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.18 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 10 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0.01 mg/dL.
- Day 121 (ECOG 0): M Protein 2.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.702 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.08 mg/dL; Immunoglobulin G 28.1 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 8.8 g/dL; Glucose 4.9 mmol/L.
- Day 204 (ECOG 1): M Protein 1.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.437 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.094 mg/dL; Immunoglobulin G 22.6 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 32.3 ×10⁹/L; Absolute Neutrophil 23.9 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 8.2 g/dL; Glucose 4.79 mmol/L.
- Day 295: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.093 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.24 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 3.8 mmol/L.
- Day 352 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.419 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 6.62 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.53 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 4.57 mmol/L.
- Day 443 (ECOG 0): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.612 mg/dL; Immunoglobulin G 8.8 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 551 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.437 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.57 mmol/L.
- Day 649 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.454 mg/dL; Immunoglobulin G 8.42 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 153 ×10⁹/L.
- Day 708: Hemoglobin 5.39 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.67 mmol/L.
- Day 831 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.974 mg/dL; Immunoglobulin G 9.88 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL; Glucose 4.57 mmol/L.
- Day 936: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.61 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.
- Day 995: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.832 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 5.33 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 1,065: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.568 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.45 mmol/L; Albumin 51 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 1,156: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.842 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 4.12 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 5.61 mmol/L.
- Day 1,219: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.702 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.48 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.64 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.57 mmol/L.

Other clinical attributes
- Day -6: Weight: 59 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1665_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1665_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
